Somatic mutation profile of tumor specimen TCGA-A5-A0GE-01A (aliquot TCGA-A5-A0GE-01A-11W-A062-09) from TCGA case TCGA-A5-A0GE, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G2; Age at diagnosis: 38.8 years (14,170 days).
Specimen TCGA-A5-A0GE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 353f8c72-2126-468c-9800-2698d3ce1b8b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A5-A0GE-10A (Blood Derived Normal), aliquot TCGA-A5-A0GE-10A-01W-A062-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e598af26-0732-430d-b1e1-ba1dcfa7b708

The open-access MAF lists 40 somatic variants for this specimen: 34 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 5, Frame Shift Del 3, Frame Shift Ins 2, Nonstop Mutation 1, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1345_1377del p.L449_K459del (on ENST00000521381 / NM_181523.3; = p.L179_K189del on NM_181504.4) | In Frame Del (DEL) | VAF 30/74 reads (41%) | hotspot (GDC flag); called by mutect2, pindel
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 93/447 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.955dup p.T319Nfs*6 | Frame Shift Ins (INS) | VAF 158/514 reads (31%) | catalogued as rs786204892, CI075686, COSV64290023; ClinVar: pathogenic; called by pindel, varscan2
- PTEN | c.1003C>G p.R335G | Missense Mutation (SNP) | VAF 145/376 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as CM971278, COSV64288687, COSV64297951; called by muse, varscan2
- ARHGAP35 | c.2612G>C p.R871P | Missense Mutation (SNP) | VAF 46/178 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.87); catalogued as COSV101351236, COSV68331934; called by muse, mutect2, varscan2
- AUTS2 | c.1613C>T p.T538M | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1384139715, COSV61407633; called by muse, mutect2, varscan2
- BPTF | c.2546G>C p.R849P | Missense Mutation (SNP) | VAF 49/181 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58836793, COSV58838635; called by muse, mutect2, varscan2
- CCDC63 | c.1032C>A p.N344K | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57528907; called by muse, mutect2
- CDH10 | c.2367A>T p.*789Yext*24 | Nonstop Mutation (SNP) | VAF 67/407 reads (16%) | catalogued as COSV52583721; called by muse, mutect2, varscan2
- CRYBG1 | c.5890del p.R1964Dfs*22 | Frame Shift Del (DEL) | VAF 26/168 reads (15%) | catalogued as COSV64812540; called by mutect2, pindel, varscan2
- CRYBG3 | c.7688G>A p.R2563Q | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs371125970; called by muse, mutect2
- DHX16 | c.821G>A p.R274Q | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.025); catalogued as rs775677381, COSV64564266; called by muse, mutect2, varscan2
- DIP2B | c.1765A>T p.M589L | Missense Mutation (SNP) | VAF 37/627 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.525); catalogued as COSV56585361; called by muse, mutect2
- DRD5 | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58577889; called by muse, mutect2, varscan2
- EMILIN2 | c.301A>G p.T101A | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.669); catalogued as COSV54424408; called by muse, mutect2
- GSG1L | c.527C>T p.A176V (on ENST00000447459 / NM_001109763.2; = p.A21V on NM_144675.2) | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as rs141366433; called by muse, mutect2, varscan2
- HECA | c.1273C>A p.H425N | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as COSV62769513; called by muse, mutect2, varscan2
- HERC1 | c.5734C>T p.R1912C | Missense Mutation (SNP) | VAF 8/127 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1250594628, COSV71247658; called by muse, mutect2
- KIAA0408 | c.1805G>T p.S602I | Missense Mutation (SNP) | VAF 31/385 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV100846990; called by muse, mutect2
- LRRN3 | c.452T>G p.L151W | Missense Mutation (SNP) | VAF 22/166 reads (13%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.923); catalogued as rs1241102045, COSV57820734; called by muse, mutect2, varscan2
- MARK4 | c.730G>T p.V244F | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764069402, COSV53464835; called by muse, mutect2, varscan2
- N4BP2 | c.5005G>A p.A1669T | Missense Mutation (SNP) | VAF 44/177 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54702783; called by muse, mutect2, varscan2
- PGLYRP1 | c.437G>A p.R146Q | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.214); catalogued as rs755262421, COSV50516471, COSV50516528; called by muse, mutect2, varscan2
- RBM47 | c.1247del p.G416Efs*29 | Frame Shift Del (DEL) | VAF 21/119 reads (18%) | catalogued as COSV99920524; called by mutect2, pindel, varscan2
- SCAF4 | c.345C>A p.N115K | Missense Mutation (SNP) | VAF 45/198 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54587960; called by muse, mutect2, varscan2
- SLC16A7 | c.1219T>C p.Y407H | Missense Mutation (SNP) | VAF 6/152 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53895871; called by muse, mutect2
- SP100 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 11/323 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50982082; called by muse, mutect2
- STAMBP | c.1271G>A p.R424Q | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780714201, COSV59897518; called by muse, mutect2, varscan2
- TENM3 | c.6605C>T p.T2202M | Missense Mutation (SNP) | VAF 46/145 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.353); catalogued as rs146065963, COSV69310305; called by muse, mutect2, varscan2
- TEX13A | c.539C>T p.A180V | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as rs1412367990, COSV100782132, COSV61161595; called by muse, mutect2, varscan2
- TXLNA | c.610C>T p.R204W | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1239533452; called by muse, mutect2
- UNC119 | c.593dup p.L199Sfs*15 | Frame Shift Ins (INS) | VAF 4/38 reads (11%) | catalogued as rs762519155; called by pindel, varscan2
- NBPF11 | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 12/366 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.811); called by muse, mutect2
- ZNF462 | c.4763_4772del p.T1588Nfs*2 | Frame Shift Del (DEL) | VAF 13/66 reads (20%) | called by mutect2, pindel, varscan2
- CADM3 | c.1071G>A p.R357= (on ENST00000368125 / NM_001127173.3; = p.R391= on NM_021189.5) | Silent (SNP) | VAF 34/110 reads (31%) | catalogued as rs1305560909, COSV63676394; called by muse, mutect2, varscan2
- LCE2C | c.267C>T p.P89= | Silent (SNP) | VAF 23/75 reads (31%) | catalogued as rs139907033; called by muse, mutect2, varscan2
- NKAP | c.45G>A p.S15= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV65056340; called by muse, mutect2, varscan2
- OTUD7A | c.1026C>T p.F342= (on ENST00000307050 / NM_001382637.1; = p.F335= on NM_130901.3) | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as rs776227673, COSV61038261; called by muse, mutect2
- ZBTB46 | c.315G>A p.V105= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as rs1469579534, COSV55510922; called by muse, mutect2, varscan2
- OR4C3 | c.-6G>T | 5'UTR (SNP) | VAF 64/416 reads (15%) | catalogued as COSV60586731; called by muse, mutect2, varscan2
